FM case AD8947 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/b4b68c04-a388-42cd-b1c4-46cb0b700ffd

Female, 52.4 years: Metaplastic carcinoma, NOS (ICD-O-3 8575/3) of the breast; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
